Surgical pathology report (de-identified scan), TCGA case TCGA-4V-A9QJ, project TCGA-THYM (Thymoma), tissue source site Hospital Louis Pradel, specimen TCGA-4V-A9QJ-01A (Primary Tumor).

Anterior mediastinum mass and contiguous lung mass

This lymphoepithelial proliferation presents with focal lobulated architecture organized around fibrotic septa. The epithelial component of the proliferation is made of polygonal large cells with eosinophilic cytoplasm, oval nucleus, and clear nucleoli. Some cytonuclear atypia are observed with large nuclei and anaplastic aspect. Necrosis is less than 10%.

Margins are negative

Distant lung parenchyma

Emphysema and vascular congestion is observed.

Interlobar, aorto-pulmonary lymph nodes

No invasion is observed

Nodule of the parietal pleura

Fibrosis is observed, some inflammation, no tumor.

Conclusion :

This is anaplastic type B3 thymoma, complete resection, stage IVA, no lymph node invasion

ICD O 3
Thymoma, type B3
malignant 88513
Site: Thymus C37.9
path
Mediastinum NOS C38.3
JW 4/2/14

Source: NCI Genomic Data Commons file 10127411-3bf2-4466-8a2c-4854230a2fcb (TCGA-4V-A9QJ.537BEDFA-F6F2-48AC-94BB-6279B07DF89D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).